Gene-level copy-number profile of tumor specimen TCGA-CV-7432-01A from TCGA case TCGA-CV-7432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 79.1 years (28,875 days).
Specimen TCGA-CV-7432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.9f80911a-3d01-40e5-96d3-ebff8a5d163a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7432-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/461b4ecf-e4bc-463b-a495-5d7ad80db857

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 924; copy number 2: 6,959; copy number 3: 9,801; copy number 4: 39,787; copy number 5: 1,639; copy number 9: 266; copy number 10: 23; copy number 13: 299; copy number 19: 2; copy number 25: 68; copy number 41: 9; copy number 56: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7432-01A-11D-2128-01): tumor purity 0.49, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 702 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,147,228–103,479,863, 702 genes, copy number 9–56 (within-gene range 2–56) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
